Somatic mutation profile of tumor specimen TCGA-DD-A4NO-01A (aliquot TCGA-DD-A4NO-01A-11D-A28X-10) from TCGA case TCGA-DD-A4NO, project TCGA-LIHC (Liver Hepatocellular Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Hepatocellular carcinoma, NOS; Tissue or organ of origin: Liver; AJCC pathologic stage: Stage I; Tumor grade: G1; Age at diagnosis: 66.0 years (24,090 days).
Specimen TCGA-DD-A4NO-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) f9a4aa72-57b8-4880-966e-a45d637d9767.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-DD-A4NO-10A (Blood Derived Normal), aliquot TCGA-DD-A4NO-10A-01D-A28X-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/453b67d4-c5da-438c-9d42-7d073e5c4724

The open-access MAF lists 58 somatic variants for this specimen: 48 protein-altering or splice-affecting, 10 silent.
By variant classification: Missense Mutation 37, Silent 10, Nonsense Mutation 3, Frame Shift Ins 3, Nonstop Mutation 1, Frame Shift Del 1, Splice Region 1, In Frame Del 1, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- NFE2L2 | c.236A>T p.E79V | Missense Mutation (SNP) | VAF 24/60 reads (40%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1057519923, COSV67960135, COSV67960407, COSV67962953; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- NFE2L2 | c.235G>T p.E79* | Nonsense Mutation (SNP) | VAF 25/60 reads (42%) | hotspot (GDC flag); catalogued as COSV67959999, COSV67960008, COSV67960140; called by muse, mutect2, varscan2
- ACY3 | c.419G>A p.C140Y | Missense Mutation (SNP) | VAF 81/166 reads (49%) | SIFT tolerated (0.42); PolyPhen possibly damaging (0.837); catalogued as COSV54828070; called by muse, mutect2, varscan2
- ALMS1 | c.7436T>A p.L2479Q | Missense Mutation (SNP) | VAF 10/192 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52502784; called by muse, mutect2
- AMER3 | c.2404C>T p.R802W | Missense Mutation (SNP) | VAF 25/113 reads (22%) | SIFT tolerated (0.21); PolyPhen benign (0); catalogued as rs140869723; called by muse, mutect2, varscan2
- ARID1B | c.4288A>G p.I1430V | Missense Mutation (SNP) | VAF 82/195 reads (42%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0); catalogued as COSV51648869; called by muse, mutect2, varscan2
- BMX | c.1424T>A p.F475Y | Missense Mutation (SNP) | VAF 85/113 reads (75%) | SIFT deleterious (0); PolyPhen possibly damaging (0.698); catalogued as COSV59590200; called by muse, mutect2, varscan2
- BPIFB2 | c.233G>A p.R78H | Missense Mutation (SNP) | VAF 33/256 reads (13%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs750355484, COSV50063112; called by muse, mutect2, varscan2
- CLHC1 | c.1760A>G p.*587Wext*7 | Nonstop Mutation (SNP) | VAF 52/124 reads (42%) | catalogued as COSV68463495; called by muse, mutect2, varscan2
- CRY1 | c.1130G>C p.G377A | Missense Mutation (SNP) | VAF 27/76 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV50481057; called by muse, mutect2, varscan2
- DOCK10 | c.5326G>T p.G1776* | Nonsense Mutation (SNP) | VAF 52/105 reads (50%) | catalogued as COSV51348042; called by muse, mutect2, varscan2
- DRAXIN | c.663C>A p.D221E | Missense Mutation (SNP) | VAF 17/116 reads (15%) | SIFT tolerated (0.37); PolyPhen benign (0.189); catalogued as COSV53841791, COSV53843515; called by muse, mutect2, varscan2
- DZIP3 | c.2086C>T p.H696Y | Missense Mutation (SNP) | VAF 44/150 reads (29%) | SIFT tolerated, low confidence (0.31); PolyPhen benign (0); catalogued as COSV64311151; called by muse, mutect2
- ERBIN | c.2144C>T p.S715L | Missense Mutation (SNP) | VAF 34/98 reads (35%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.057); catalogued as rs760228126, COSV52310795, COSV52329712; called by muse, mutect2, varscan2
- FASN | c.5768G>A p.G1923D | Missense Mutation (SNP) | VAF 54/110 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV60750418; called by muse, varscan2
- FLT4 | c.2006A>G p.Y669C | Missense Mutation (SNP) | VAF 56/164 reads (34%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.962); catalogued as COSV56098323; called by muse, mutect2, varscan2
- GDAP2 | c.355A>T p.N119Y | Missense Mutation (SNP) | VAF 56/115 reads (49%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.883); catalogued as COSV101031887; called by muse, mutect2, varscan2
- GDAP2 | c.354C>A p.F118L | Missense Mutation (SNP) | VAF 56/116 reads (48%) | SIFT deleterious (0.03); PolyPhen benign (0.138); catalogued as COSV101031891; called by muse, mutect2, varscan2
- GFOD2 | c.359T>C p.V120A | Missense Mutation (SNP) | VAF 42/138 reads (30%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.493); catalogued as COSV52056869; called by muse, mutect2, varscan2
- GZMA | c.169G>A p.A57T | Missense Mutation (SNP) | VAF 20/41 reads (49%) | SIFT tolerated (0.29); PolyPhen benign (0.087); catalogued as COSV57111922; called by muse, mutect2, varscan2
- HECTD4 | c.12731G>A p.R4244Q | Missense Mutation (SNP) | VAF 21/62 reads (34%) | SIFT tolerated (0.06); PolyPhen benign (0.005); catalogued as rs564542020, COSV66386693; called by muse, mutect2, varscan2
- HIPK2 | c.215C>T p.P72L | Missense Mutation (SNP) | VAF 80/372 reads (22%) | SIFT tolerated (0.31); PolyPhen benign (0.015); catalogued as rs748732904, COSV100701940, COSV61225609; called by muse, mutect2, varscan2
- HTT | c.1121C>A p.T374N | Missense Mutation (SNP) | VAF 42/106 reads (40%) | SIFT tolerated (0.24); PolyPhen probably damaging (0.994); catalogued as COSV61857399; called by muse, mutect2, varscan2
- ICE1 | c.1793A>G p.D598G | Missense Mutation (SNP) | VAF 27/97 reads (28%) | SIFT tolerated (0.5); PolyPhen benign (0.003); catalogued as COSV56819084; called by muse, mutect2, varscan2
- KIAA1328 | c.987G>C p.K329N | Missense Mutation (SNP) | VAF 18/228 reads (8%) | SIFT tolerated (0.25); PolyPhen benign (0.007); catalogued as COSV54447486, COSV99694422; called by muse, mutect2
- LAMA5 | c.7085A>C p.E2362A | Missense Mutation (SNP) | VAF 26/247 reads (11%) | SIFT tolerated (0.23); PolyPhen benign (0.138); catalogued as COSV53352941; called by muse, mutect2
- LPA | c.3347C>A p.T1116N | Missense Mutation (SNP) | VAF 28/129 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.93); catalogued as COSV60296755; called by muse, mutect2, varscan2
- LRIG1 | c.645A>G p.Q215= | Splice Region (SNP) | VAF 29/105 reads (28%) | catalogued as COSV56236698; called by muse, mutect2, varscan2
- LRP4 | c.290A>T p.E97V | Missense Mutation (SNP) | VAF 70/176 reads (40%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.67); catalogued as rs766174802, COSV66133996; called by muse, mutect2, varscan2
- MED13 | c.2272C>T p.R758C | Missense Mutation (SNP) | VAF 51/177 reads (29%) | SIFT tolerated (0.08); PolyPhen benign (0.006); catalogued as rs745497498, COSV67261923; called by muse, mutect2, varscan2
- MYRF | c.2385G>C p.E795D (on ENST00000278836 / NM_001127392.3; = p.E786D on NM_013279.4) | Missense Mutation (SNP) | VAF 66/359 reads (18%) | SIFT tolerated (0.35); PolyPhen benign (0.01); catalogued as COSV53885795; called by muse, mutect2, varscan2
- OPLAH | c.3631C>G p.P1211A | Missense Mutation (SNP) | VAF 13/42 reads (31%) | SIFT tolerated (0.18); PolyPhen benign (0.015); catalogued as COSV66298035; called by muse, mutect2, varscan2
- PDE12 | c.596A>C p.K199T | Missense Mutation (SNP) | VAF 38/108 reads (35%) | SIFT deleterious (0.01); PolyPhen benign (0.04); catalogued as COSV60818148; called by muse, mutect2, varscan2
- PLEKHG2 | c.2920G>A p.D974N | Missense Mutation (SNP) | VAF 77/156 reads (49%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.505); catalogued as COSV52678402; called by muse, mutect2, varscan2
- RCOR3 | c.1232T>A p.L411Q | Missense Mutation (SNP) | VAF 62/184 reads (34%) | SIFT tolerated (0.11); PolyPhen benign (0.202); catalogued as COSV65364564; called by muse, mutect2, varscan2
- RET | c.334C>T p.R112C | Missense Mutation (SNP) | VAF 20/68 reads (29%) | SIFT tolerated, low confidence (0.17); PolyPhen benign (0.014); catalogued as rs762626209; ClinVar: uncertain significance; called by muse, mutect2
- SPEG | c.4711G>T p.E1571* | Nonsense Mutation (SNP) | VAF 48/115 reads (42%) | catalogued as COSV56663078, COSV56668154; called by muse, mutect2, varscan2
- TIMM13 | c.154G>A p.G52R | Missense Mutation (SNP) | VAF 22/65 reads (34%) | SIFT tolerated (0.36); PolyPhen benign (0.048); catalogued as COSV53113568; called by muse, mutect2, varscan2
- TLN2 | c.3540T>G p.D1180E | Missense Mutation (SNP) | VAF 56/254 reads (22%) | SIFT deleterious (0.05); PolyPhen benign (0.206); catalogued as COSV60885574; called by muse, varscan2
- UGT2B4 | c.1087_1089del p.L363del | In Frame Del (DEL) | VAF 16/69 reads (23%) | catalogued as rs1317780715; called by pindel, varscan2
- UMOD | c.1894T>A p.S632T | Missense Mutation (SNP) | VAF 12/431 reads (3%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV56775175; called by muse, mutect2
- UNC13A | c.4696C>T p.R1566W | Missense Mutation (SNP) | VAF 69/188 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV53188416; called by muse, mutect2, varscan2
- ZNF654 | c.2497G>A p.A833T | Missense Mutation (SNP) | VAF 18/65 reads (28%) | SIFT tolerated (0.28); PolyPhen probably damaging (0.998); catalogued as COSV58804894; called by muse, mutect2, varscan2
- ZNF827 | c.2860+1G>C p.X954_splice | Splice Site (SNP) | VAF 40/139 reads (29%) | catalogued as COSV65224861; called by muse, mutect2, varscan2
- CYSLTR1 | c.417dup p.A140Sfs*28 | Frame Shift Ins (INS) | VAF 36/68 reads (53%) | called by mutect2, pindel, varscan2
- PDE7A | c.1179dup p.Y394Ifs*14 (on ENST00000401827 / NM_001242318.3; = p.Y368Ifs*14 on NM_002603.4) | Frame Shift Ins (INS) | VAF 24/52 reads (46%) | called by mutect2, varscan2
- PIKFYVE | c.5765del p.K1922Rfs*11 | Frame Shift Del (DEL) | VAF 12/42 reads (29%) | called by mutect2, pindel, varscan2
- SEC31B | c.1076dup p.P361Tfs*25 | Frame Shift Ins (INS) | VAF 20/92 reads (22%) | called by mutect2, pindel, varscan2
- ABTB2 | c.1575A>C p.P525= | Silent (SNP) | VAF 18/113 reads (16%) | catalogued as COSV54384061; called by muse, mutect2, varscan2
- ALPK3 | c.2733A>C p.T911= | Silent (SNP) | VAF 49/94 reads (52%) | catalogued as COSV51929329; called by muse, mutect2, varscan2
- BAZ1A | c.1624T>C p.L542= | Silent (SNP) | VAF 4/16 reads (25%) | catalogued as COSV62409000; called by muse, mutect2, varscan2
- CDH9 | c.2364A>C p.R788= | Silent (SNP) | VAF 56/143 reads (39%) | catalogued as COSV50252320; called by muse, mutect2, varscan2
- CLN5 | c.21G>C p.T7= | Silent (SNP) | VAF 5/34 reads (15%) | catalogued as rs1057521258, COSV66283447; ClinVar: likely benign; called by muse, mutect2
- ESRP1 | c.1116C>T p.D372= | Silent (SNP) | VAF 120/204 reads (59%) | catalogued as rs748528710, COSV64407817; called by muse, varscan2
- OR6N2 | c.39G>T p.V13= | Silent (SNP) | VAF 125/439 reads (28%) | catalogued as COSV59410062; called by muse, mutect2, varscan2
- SLC10A2 | c.510T>A p.V170= | Silent (SNP) | VAF 23/87 reads (26%) | catalogued as COSV55357072; called by muse, mutect2, varscan2
- THSD7A | c.4164T>C p.C1388= | Silent (SNP) | VAF 48/137 reads (35%) | catalogued as COSV69855411; called by muse, mutect2, varscan2
- ZBTB18 | c.1272C>A p.T424= | Silent (SNP) | VAF 231/493 reads (47%) | catalogued as rs375286592; called by muse, mutect2, varscan2
